Somatic mutation profile of tumor specimen BA3367D (aliquot aq-BA3367D) from BEATAML1.0 case 2730, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Tissue or organ of origin: Bone marrow.
Specimen BA3367D: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 911fc5f2-5a7c-412e-9554-eb2a8abc5fde.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3441D (Solid Tissue Normal), aliquot aq-BA3441D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8dc1ba04-f211-490c-adbe-660af2fbbe70

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- UNC5B | c.1035dup p.K346* | Frame Shift Ins (INS) | VAF 26/68 reads (38%) | called by mutect2, pindel, varscan2
